Somatic mutation profile of tumor specimen TCGA-PL-A8LY-01A (aliquot TCGA-PL-A8LY-01A-11D-A41F-09) from TCGA case TCGA-PL-A8LY, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 30.7 years (11,199 days).
Specimen TCGA-PL-A8LY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe6e3336-2263-4fea-ab3e-df2ba1dbee5a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-PL-A8LY-10A (Blood Derived Normal), aliquot TCGA-PL-A8LY-10A-01D-A41F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/044e5f26-5496-44d1-9191-e69448047a16

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PALLD | c.3349G>T p.D1117Y (on ENST00000505667 / NM_001166108.2; = p.D1100Y on NM_016081.4) | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54989020, COSV99823517; called by muse, mutect2
- GRIN2C | c.2142G>A p.A714= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs923185095, COSV53111693; called by muse, mutect2
